Somatic mutation profile of tumor specimen TCGA-HD-8224-01A (aliquot TCGA-HD-8224-01A-11D-2394-08) from TCGA case TCGA-HD-8224, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 63.2 years (23,069 days).
Specimen TCGA-HD-8224-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f813abcc-f56e-4e9f-9c98-e410afbd7854.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HD-8224-10A (Blood Derived Normal), aliquot TCGA-HD-8224-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c2928c2-1d32-421a-aee2-d93bbb811ab6

The open-access MAF lists 76 somatic variants for this specimen: 61 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 14, Nonsense Mutation 4, In Frame Del 2, Frame Shift Ins 1, Splice Site 1, Translation Start Site 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 29/43 reads (67%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3644C>G p.S1215C (on ENST00000404938 / NM_001163941.2; = p.S770C on NM_178559.6) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99327626, COSV99328845; called by muse, mutect2, varscan2
- ACTR10 | c.1131T>A p.Y377* | Nonsense Mutation (SNP) | VAF 5/90 reads (6%) | catalogued as COSV99581242; called by muse, mutect2
- AGPAT3 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as COSV99377640; called by muse, mutect2, varscan2
- ALB | c.79C>T p.H27Y | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs141733599, CM940018; ClinVar: other; called by muse, mutect2, varscan2
- ANKMY2 | c.164A>T p.Y55F | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.498); catalogued as COSV100187167; called by muse, mutect2, varscan2
- AOC2 | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99513702; called by muse, mutect2, varscan2
- ARAP3 | c.3463C>T p.R1155W | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs554433565, COSV99499964; called by muse, mutect2
- ATXN1 | c.1088T>C p.V363A | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV99786863; called by muse, mutect2, varscan2
- BRDT | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs140481537; called by muse, mutect2, varscan2
- CASR | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 78/266 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as rs1064794290, CM076073, COSV56138551; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBLN4 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99290613; called by muse, mutect2, varscan2
- CCDC197 | c.50A>C p.D17A | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV100113678; called by muse, mutect2, varscan2
- CHD5 | c.2851G>A p.E951K | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99314172; called by muse, mutect2, varscan2
- CTAGE1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 90/261 reads (34%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.939); catalogued as COSV101194597; called by muse, mutect2, varscan2
- CYP2C19 | c.1160T>C p.I387T | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs562912432, COSV100990561; called by muse, mutect2, varscan2
- DCLK2 | c.1874A>T p.K625M | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV99652367; called by muse, mutect2, varscan2
- DGKQ | c.2344G>C p.V782L | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as rs537203372, COSV99297973; called by muse, mutect2, varscan2
- DSG4 | c.2807C>A p.T936N | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100356089, COSV100356261; called by muse, mutect2, varscan2
- DYNC2I1 | c.3015G>T p.M1005I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs758602350, COSV101337704; called by muse, varscan2
- ENTPD8 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.261); catalogued as COSV100395631; called by muse, mutect2, varscan2
- ESRRB | c.769T>A p.W257R | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99835486; called by muse, mutect2, varscan2
- GLIPR2 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.988); catalogued as rs200040826, COSV100936958; called by muse, mutect2, varscan2
- GRIN2B | c.1714G>A p.V572M | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.044); catalogued as rs750935831, COSV74205741; called by muse, mutect2, varscan2
- IDH1 | c.929G>T p.G310V | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV61621146; called by muse, mutect2, varscan2
- ITGB8 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as COSV99751808; called by muse, mutect2, varscan2
- KANK4 | c.1331G>C p.S444T | Missense Mutation (SNP) | VAF 89/267 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.053); catalogued as rs748384829, COSV100587514; called by muse, mutect2, varscan2
- KIF26A | c.3641C>T p.P1214L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs747471698, COSV100180837, COSV100181321; called by muse, mutect2, varscan2
- LRR1 | c.252G>T p.K84N | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as COSV100023198; called by muse, mutect2, varscan2
- MED13L | c.5667G>C p.M1889I | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV99929299; called by muse, mutect2, varscan2
- MXRA5 | c.6355C>T p.R2119C | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV54234496; called by muse, mutect2, varscan2
- MYLK2 | c.1525G>A p.V509I | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.172); catalogued as rs183224373, COSV65659406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO16 | c.1660A>G p.I554V | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.871); catalogued as rs1226385589, COSV99194138; called by muse, mutect2, varscan2
- NR2F1 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59068138; called by muse, mutect2, varscan2
- P3H2 | c.1229+1G>A p.X410_splice | Splice Site (SNP) | VAF 38/167 reads (23%) | catalogued as COSV100077945; called by muse, mutect2, varscan2
- PCDH15 | c.4645G>T p.V1549L | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV100223335; called by muse, mutect2, varscan2
- PFKM | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1022005929, COSV56660361; called by muse, mutect2, varscan2
- RIF1 | c.6448G>T p.E2150* | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | catalogued as COSV99690821; called by muse, mutect2, varscan2
- RUFY3 | c.971T>C p.L324P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as rs779923378, COSV99887573; called by muse, mutect2, varscan2
- RYR3 | c.9553A>T p.I3185F (on ENST00000389232; = p.I3186F on NM_001036.6) | Missense Mutation (SNP) | VAF 67/378 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV101213153; called by muse, mutect2, varscan2
- SECISBP2L | c.2965G>C p.E989Q (on ENST00000559471 / NM_001193489.2; = p.E944Q on NM_014701.4) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV55937513, COSV99960570; called by muse, mutect2, varscan2
- SERPINB12 | c.579C>G p.F193L | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV99501734; called by muse, mutect2
- SFXN2 | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100882752; called by muse, mutect2
- STXBP5 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV99470560; called by muse, mutect2, varscan2
- SYNE1 | c.18175A>G p.M6059V (on ENST00000367255 / NM_182961.4; = p.M5988V on NM_033071.3) | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99570441; called by muse, mutect2, varscan2
- TAS2R1 | c.200T>G p.V67G | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV101225804, COSV66779025; called by muse, mutect2
- TEX55 | c.449T>A p.L150* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as COSV99817629; called by muse, mutect2, varscan2
- TGIF2LX | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1311902088, COSV99383439; called by muse, mutect2, varscan2
- TMEM254 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as rs1321826626, COSV100953571; called by muse, mutect2, varscan2
- TNXB | c.8242G>A p.E2748K (on ENST00000647633; = p.E2501K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs1274678608, COSV64491661; called by muse, mutect2, varscan2
- USF3 | c.4634C>G p.T1545S | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.077); catalogued as COSV100325498; called by muse, mutect2, varscan2
- USP31 | c.3344A>G p.Q1115R | Missense Mutation (SNP) | VAF 82/164 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV99565462; called by muse, mutect2, varscan2
- VCAN | c.8631A>T p.K2877N | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV99426405; called by muse, mutect2
- CCL23 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- CDKN2A | c.43_62del p.W15Pfs*22 | Frame Shift Del (DEL) | VAF 29/43 reads (67%) | called by mutect2, pindel
- FHOD3 | c.2083_2097del p.K695_E699del (on ENST00000359247 / NM_001281739.3; = p.K712_E716del on NM_025135.5) | In Frame Del (DEL) | VAF 26/67 reads (39%) | called by mutect2, pindel, varscan2
- LEPR | c.1976dup p.N659Kfs*13 | Frame Shift Ins (INS) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- OR2A1 | c.582C>A p.N194K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by mutect2, varscan2
- PAG1 | c.-1_22del | Translation Start Site (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- PRKACG | c.577_597del p.K193_L199del | In Frame Del (DEL) | VAF 12/33 reads (36%) | called by mutect2, pindel, varscan2
- ZMYND11 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 14/443 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ADGRB3 | c.3831G>A p.L1277= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV99485929; called by muse, mutect2, varscan2
- B3GNT8 | c.852G>A p.R284= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs1453853235, COSV54196337; called by muse, mutect2, varscan2
- CPS1 | c.4137A>G p.E1379= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as COSV99243456; called by muse, mutect2, varscan2
- DCP1A | c.1527G>A p.Q509= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99588071; called by muse, mutect2, varscan2
- DCST2 | c.2157C>G p.P719= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV99421330; called by muse, mutect2, varscan2
- DSG4 | c.2808C>A p.T936= | Silent (SNP) | VAF 60/156 reads (38%) | catalogued as COSV100356091, COSV57388886; called by muse, mutect2, varscan2
- ESF1 | c.834G>A p.E278= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as COSV99176421; called by muse, mutect2, varscan2
- MUC4 | c.2526G>A p.Q842= | Silent (SNP) | VAF 24/121 reads (20%) | catalogued as COSV100640996; called by muse, mutect2, varscan2
- PBRM1 | c.3894G>A p.Q1298= (on ENST00000296302 / NM_001366071.2; = p.Q1273= on NM_018313.5) | Silent (SNP) | VAF 5/102 reads (5%) | catalogued as COSV56313242; called by muse, mutect2
- PLAGL1 | c.174C>T p.P58= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as rs904632834, COSV99394559; called by muse, mutect2
- SLC38A9 | c.1413C>T p.F471= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs1284675751, COSV100591495; called by muse, mutect2, varscan2
- SLC5A12 | c.141A>G p.Q47= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as COSV99745151; called by muse, mutect2, varscan2
- TLR10 | c.684T>C p.F228= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100457771; called by muse, mutect2, varscan2
- ZNF668 | c.231C>T p.S77= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs1224381793, COSV100336747; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505308 T>C | 5'Flank (SNP) | VAF 12/43 reads (28%) | called by muse, mutect2, varscan2
